FM case AD13172 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/7384a458-b635-4c75-89a5-c5902ebf35b2

Female, 65.5 years: Adenocarcinoma, diffuse type (ICD-O-3 8145/3) of the stomach; primary biopsied or resected from the stomach. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
